CCDI case PBBKDK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c0d02bca-3dd8-4923-8dde-94f57b033cd1

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.3 years (5,961 days).

Biospecimens (3 samples)
- Sample 0DAOBN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAOBO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAOBP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
